Surgical pathology report (de-identified scan), TCGA case TCGA-SW-A7EA, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Global Bioclinical-Moldova, specimen TCGA-SW-A7EA-01A (Primary Tumor).

Final Pathology Template

Subject ID

Final Pathology Report Information (Surgical Tissue Case)

- 1.1 Tissue Specimen ID Code:
- 1.2 Date of Excision: (MM/DD/YYYY)
- 1.3 Tumor Location (anatomic site): **Stomach, Antrum**
- 1.4 Tumor Size: **3.0x 4.0 (cm)**
- 1.5 Lymph Node Status:
- 1.5.1 Number Nodes Examined: **11**
- 1.5.2 Number Nodes Positive: **0**
- 1.5.3 Lymph Node Locations (Involved Nodes): **8 greater curvature, 3 lesser curvature**
- 1.6 Metastasis:
- 1.6.1 Metastasis Present: ☐ Yes ☒ No ☐ Unknown
- 1.6.2 Number of Mets: _____
- 1.6.3 Site(s) Of Metastasis: _____
- 1.7 ICD-9 Code for Specimen Diagnosis: **C 16.3**
- 1.8 Final Pathology Details:
(Please supply de-identified copy of original language final pathology report in addition to information below)

ICD 16.3

Adenocarcinoma, diffuse
type + signet ring cell
Code to highest 849013

Site: gastric antrum C16.3

9/30/13

- 1.8.1 Macroscopic Description: **Surgical specimen of stomach, measuring 16 cm in combination with greater omentum. At 1.0 cm from the resection margin, ulcerative formation with irregular borders 3.0 x 4.0 cm in dimension, macroscopically not infiltrating gastric wall. Greater omentum is intact. 11 lymph nodes (8 - greater curvatures, 3 - lesser curvature).**
- 1.8.2 Microscopic Description: **Adenocarcinoma diffuse type undifferentiated of stomach, with signet ring cell type regions. Tumor invades through muscularis propria. Margins resection is intact. Greater omentum is intact. Lymph node status negative: greater curvature (8 from 8) and lesser curvature (3 from 3).**
- 1.8.3 Comment (if applicable): _____
- 1.8.4 Clinical Diagnosis: **Gastric cancer of antrum**
- 1.8.5 Stage: **T2a N0 M0 (TxNxMx)**

PROPRIETARY AND CONFIDENTIAL

HIF1A Discrepancy		☒

Source: NCI Genomic Data Commons file d6d83e4b-2b65-43b2-9f7a-2ece8b3c9829 (TCGA-SW-A7EA.77B78001-43C6-45D3-B591-1C3F62138E83.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).